Somatic mutation profile of tumor specimen TARGET-10-PAREGZ-09A (aliquot TARGET-10-PAREGZ-09A-01D) from TARGET case TARGET-10-PAREGZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.6 years (3,128 days).
Specimen TARGET-10-PAREGZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f1096eb-d5b5-4bd9-a72e-01a14f9a66ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREGZ-14A (Bone Marrow Normal), aliquot TARGET-10-PAREGZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12d1f987-b01d-4d72-997c-6ac043ebe8c4

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DACH2 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV64167874, COSV64174007; called by muse, mutect2, varscan2
- MAST2 | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.677); catalogued as rs967794723, COSV63618918; called by muse, mutect2, varscan2
- NHSL2 | c.526T>A p.S176T (on ENST00000510661; = p.S542T on NM_001013627.2) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV65453793; called by muse, mutect2, varscan2
- NOTCH1 | c.4721T>C p.L1574P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024760, COSV53072929; called by muse, mutect2, varscan2
- PPP1R36 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs776262589; called by muse, mutect2
- TRBJ2-5 | c.4C>T p.Q2* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs1554511737; called by mutect2, varscan2
- TRBJ2-5 | c.1_2insACACGTATCTTTAGTT p.Q2Hfs*? | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | called by mutect2, varscan2
- ALB | c.1437G>A p.V479= | Silent (SNP) | VAF 55/96 reads (57%) | called by muse, mutect2, varscan2
- PAK5 | c.1953G>A p.A651= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs201731869, COSV62037947; called by muse, mutect2, varscan2
- RASD2 | c.483G>A p.S161= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as rs138302702, COSV99332701; called by muse, mutect2, varscan2
- WNK2 | c.6740-9C>G | Intron (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
